Gene-level copy-number profile of tumor specimen TCGA-91-6847-01A from TCGA case TCGA-91-6847, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 62.6 years (22,862 days).
Specimen TCGA-91-6847-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.bd42c4a4-9265-4d6d-a581-72e3b27beb59.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-91-6847-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e50b75b7-1ee1-4432-b5a4-c6563f1e4c7a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 819; copy number 2: 11,732; copy number 3: 19,105; copy number 4: 13,094; copy number 5: 8,343; copy number 6: 3,897; copy number 7: 723; copy number 8: 618; copy number 9: 996; copy number 10: 241; copy number 11: 74; copy number 12: 107; copy number 15: 11; copy number 49: 58.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-91-6847-01A-11D-1943-01): tumor purity 0.85, ploidy 3.59, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,828 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:16,661,907–20,575,873, 66 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr6:21,233,168–22,675,493, 17 genes, copy number 8: AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2.
- chr6:27,018,935–28,923,988, 112 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr7:54,542,325–56,323,601, 58 genes, copy number 49: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, AC011228.3, AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1.
- chr8:40,161,458–40,897,833, 5 genes, copy number 9 (within-gene range 3–9): AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4.
- chr8:49,046,652–55,542,054, 78 genes, copy number 8–10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:80,812,142–91,907,619, 147 genes, copy number 7–12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:96,645,242–99,895,121, 57 genes, copy number 7–9 (within-gene range 6–9): CPQ, AP003117.2, AP003117.1, AP003115.1, TSPYL5, SNORD3H, AP002982.1, AP002982.2, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1.
- chr8:104,330,324–106,981,571, 30 genes, copy number 7–9: DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1, AC041039.1, ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA, AP003789.1.
- chr8:117,794,490–140,635,633, 289 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr10:133,160,219–133,761,125, 51 genes, copy number 10: KNDC1, UTF1, VENTX, MIR202HG, MIR202, AL592071.1, ADAM8, TUBGCP2, AL360181.2, ZNF511, ZNF511-PRAP1, CALY, BANF1P2, AL360181.1, PRAP1, FUOM, ECHS1, MIR3944, AL360181.4, PAOX, AL360181.3, MTG1, SPRN, OR6L2P, SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15.
- chr11:128,458,761–130,033,220, 28 genes, copy number 12–15 (within-gene range 3–15): ETS1, MIR6090, ETS1-AS1, AP001122.1, FLI1, SENCR, KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395, AP003327.2, AP003327.1, TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2.
- chr13:78,761,175–80,134,368, 18 genes, copy number 8: RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1.
- chr13:86,266,842–86,462,734, 3 genes, copy number 9: FO624990.1, DDX6P2, AL445207.1.
- chr13:87,890,172–114,337,626, 378 genes, copy number 8 (broad region; genes not listed).
- chr14:18,333,726–44,567,467, 733 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr17:17,972,813–18,039,209, 2 genes, copy number 9 (within-gene range 2–9): DRC3, ATPAF2.
- chr17:18,010,643–20,319,026, 134 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:22,266,395–22,332,410, 4 genes, copy number 9 (within-gene range 6–9): AC138761.1, AC138761.2, FAM27E5, AC087575.1.
- chr17:69,147,214–78,782,297, 283 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr17:80,466,834–83,095,122, 151 genes, copy number 7 (broad region; genes not listed).
- chr22:23,059,415–23,583,859, 23 genes, copy number 7 (within-gene range 6–7): RSPH14, GNAZ, Metazoa_SRP, U7, RAB36, BCR, BCRP8, RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2.
- chr22:30,902,219–36,703,752, 161 genes, copy number 11–12 (within-gene range 3–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 819. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
